Somatic mutation profile of tumor specimen 0DFRTI from CCDI case PBBRLR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Sclerosing stromal tumor; Tissue or organ of origin: Fallopian tube; Age at diagnosis: 14.3 years (5,217 days).
Specimen 0DFRTI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 742116d7-a9ce-44a8-ab34-d4af62aa3f80.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFRTJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/631bc34d-9025-4e66-adb5-12887d360514

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IGDCC4 | c.3632C>T p.P1211L | Missense Mutation (SNP) | VAF 112/317 reads (35%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs560887461, COSV61537226; called by muse, varscan2
